Somatic mutation profile of tumor specimen TCGA-68-A59J-01A (aliquot TCGA-68-A59J-01A-21D-A26M-08) from TCGA case TCGA-68-A59J, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.0 years (27,031 days).
Specimen TCGA-68-A59J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3560c5b-b79d-417c-be42-2b126a0835a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-68-A59J-10A (Blood Derived Normal), aliquot TCGA-68-A59J-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e540f198-5035-483d-95c4-c0c0a265b78f

The open-access MAF lists 418 somatic variants for this specimen: 303 protein-altering or splice-affecting, 107 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 107, Nonsense Mutation 18, Frame Shift Del 14, Intron 5, Splice Site 4, Frame Shift Ins 3, Splice Region 3, RNA 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | hotspot (GDC flag); catalogued as rs121913384, CM034218, CM095540, COSV58683071, COSV58683670; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67959995, COSV67960100, COSV67961494; called by mutect2, varscan2
- TP53 | c.515T>A p.V172D | Missense Mutation (SNP) | VAF 29/52 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52683521, COSV52729554, COSV52811339, COSV52993405; called by muse, mutect2, varscan2
- ABCA1 | c.2782A>T p.I928F | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV101037120; called by muse, mutect2, varscan2
- ABCB5 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.919); catalogued as COSV99328607; called by muse, mutect2, varscan2
- ABCC5 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV99657014; called by muse, mutect2
- ABCC6 | c.2935G>T p.G979W | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228946; called by muse, mutect2
- ABL2 | c.1600G>A p.E534K (on ENST00000502732 / NM_007314.4; = p.E519K on NM_005158.5) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV100772808; called by muse, mutect2, varscan2
- ABR | c.937G>A p.E313K (on ENST00000302538 / NM_021962.5; = p.E276K on NM_001092.5) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99348094; called by muse, mutect2, varscan2
- AC011448.1 | c.55A>G p.I19V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.067); catalogued as COSV99389102; called by muse, mutect2, varscan2
- ACRV1 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.044); catalogued as COSV100223575; called by muse, mutect2, varscan2
- ACSM2B | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100312781; called by muse, mutect2, varscan2
- ADAMTS12 | c.1279C>A p.P427T | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.137); catalogued as COSV100711106; called by muse, mutect2, varscan2
- ADAMTS2 | c.1422C>A p.D474E | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99202352; called by muse, mutect2, varscan2
- ADAMTS4 | c.1093C>T p.H365Y | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100917472, COSV63488799; called by muse, mutect2, varscan2
- ADGRV1 | c.7615C>A p.L2539I | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as COSV101316090, COSV67980212; called by muse, mutect2, varscan2
- AKAP13 | c.3818G>T p.G1273V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV100773934; called by muse, mutect2, varscan2
- ALDH3B2 | c.987G>T p.M329I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100824062; called by muse, mutect2
- AMY2B | c.49T>A p.Y17N | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.374); catalogued as COSV100796342; called by muse, mutect2, varscan2
- ANK2 | c.4187G>A p.G1396D | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100002062; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3355G>C p.E1119Q | Missense Mutation (SNP) | VAF 81/143 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99781899; called by muse, mutect2, varscan2
- ANKRD34B | c.1097C>G p.A366G | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.549); catalogued as COSV100103551, COSV58614015; called by muse, mutect2, varscan2
- APOB | c.4382G>T p.W1461L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99266056; called by muse, mutect2, varscan2
- ARHGAP27 | c.1114G>A p.E372K (on ENST00000428638 / NM_001282290.1; = p.E31K on NM_199282.3) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV100976547; called by muse, mutect2, varscan2
- ARID3B | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.102); catalogued as COSV100654661; called by muse, mutect2, varscan2
- ASMT | c.965C>A p.S322Y (on ENST00000381229; = p.S350Y on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV101172482; called by muse, mutect2, varscan2
- ASPM | c.707G>T p.C236F | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs764828729, COSV99660541; called by muse, mutect2, varscan2
- ATP11B | c.1424C>G p.P475R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV100017844; called by muse, mutect2
- BMP5 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.039); catalogued as COSV100896009; called by muse, mutect2, varscan2
- BPIFB6 | c.154G>C p.G52R | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV100848527; called by muse, mutect2, varscan2
- BRAF | c.629G>T p.W210L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56185391, COSV99962917; called by muse, mutect2, varscan2
- BRINP3 | c.1032G>T p.L344F | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.111); catalogued as COSV100818623, COSV100818936; called by muse, mutect2, varscan2
- BTBD7 | c.3337A>T p.I1113L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100597923; called by muse, mutect2, varscan2
- BTBD7 | c.3178G>A p.V1060I | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs904585282, COSV100597928; called by muse, mutect2, varscan2
- C11orf24 | c.1222C>T p.L408F | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as COSV100422597; called by muse, mutect2
- C16orf92 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV99662464; called by muse, mutect2
- C6orf118 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.592); catalogued as COSV100024585; called by muse, mutect2, varscan2
- C6orf118 | c.897G>T p.M299I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV100024586; called by muse, mutect2, varscan2
- C8A | c.1162A>T p.I388L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100776521; called by muse, mutect2, varscan2
- C9 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV54679073, COSV99662133; called by muse, mutect2, varscan2
- CAD | c.2604T>A p.C868* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV99255188; called by muse, mutect2, varscan2
- CAMK2A | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.78); catalogued as COSV62244836; called by muse, mutect2, varscan2
- CARMIL3 | c.277A>T p.S93C | Missense Mutation (SNP) | VAF 140/213 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV100549640; called by muse, mutect2, varscan2
- CASS4 | c.1354G>C p.V452L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100824742; called by muse, mutect2, varscan2
- CBLN4 | c.375C>A p.H125Q | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99290584; called by muse, mutect2, varscan2
- CCDC180 | c.210G>C p.W70C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100826864; called by muse, mutect2, varscan2
- CCDC80 | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99244869; called by muse, mutect2, varscan2
- CCND2 | c.673T>G p.C225G | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99714278; called by muse, mutect2, varscan2
- CCNF | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99563748; called by muse, mutect2, varscan2
- CD200 | c.760G>T p.V254F (on ENST00000473539 / NM_001004196.3; = p.V229F on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV100238359; called by muse, mutect2, varscan2
- CDH10 | c.383G>C p.R128P | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100051837; called by muse, mutect2, varscan2
- CDH15 | c.398A>T p.E133V | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228503; called by muse, mutect2, varscan2
- CEL | c.130G>T p.G44C (on ENST00000673714; = p.G41C on NM_001807.6) | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV100672542; called by muse, mutect2, varscan2
- CENPE | c.2663A>T p.E888V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV99478174; called by muse, mutect2, varscan2
- CEP20 | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV99739621, COSV99739870; called by muse, mutect2, varscan2
- CILP2 | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1383709843, COSV52273596; called by muse, mutect2, varscan2
- CLEC17A | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as COSV100355390, COSV60428982; called by muse, mutect2, varscan2
- CNOT3 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs775550862, COSV55362727; called by muse, mutect2, varscan2
- CNTNAP5 | c.3383C>A p.P1128Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs764158287, COSV101443671, COSV70482712; called by muse, mutect2, varscan2
- COG8 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99650759; called by muse, mutect2, varscan2
- COL27A1 | c.5413G>T p.E1805* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100621044; called by muse, mutect2, varscan2
- COL4A1 | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101011252; called by muse, mutect2, varscan2
- COL4A2 | c.3053G>T p.G1018V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64627785; called by muse, mutect2, varscan2
- CPXCR1 | c.317T>C p.L106S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV99342238; called by muse, mutect2, varscan2
- CRYBG3 | c.6313C>G p.P2105A | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51712631, COSV99477074; called by muse, mutect2, varscan2
- CSF2RB | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV99453980; called by muse, mutect2, varscan2
- CSMD3 | c.7234G>A p.E2412K (on ENST00000297405 / NM_001363185.1; = p.E2308K on NM_052900.3) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99836686; called by muse, mutect2, varscan2
- CTC1 | c.3012C>T p.S1004= | Splice Region (SNP) | VAF 39/87 reads (45%) | catalogued as rs772609095, COSV59853098; called by muse, mutect2, varscan2
- CTCF | c.255A>T p.E85D | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.067); catalogued as COSV99865623; called by muse, mutect2, varscan2
- CTNNA3 | c.2052G>C p.K684N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101041421; called by muse, mutect2, varscan2
- CTNNA3 | c.1276G>A p.V426I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs576608598, COSV101050023; called by muse, mutect2, varscan2
- DDI2 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 25/56 reads (45%) | catalogued as rs1416854324, COSV100197657; called by muse, mutect2, varscan2
- DGKD | c.602C>A p.A201D (on ENST00000264057 / NM_152879.3; = p.A157D on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99896553; called by muse, mutect2
- DGKK | c.1025A>T p.N342I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101053056; called by muse, mutect2, varscan2
- DNASE1L3 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV100568738; called by muse, mutect2
- DNHD1 | c.11900C>G p.T3967R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.216); catalogued as rs753173492, COSV99600314; called by muse, mutect2, varscan2
- DYNC1H1 | c.7899G>C p.K2633N | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100795011; called by muse, mutect2, varscan2
- EGFLAM | c.2614G>T p.A872S (on ENST00000354891 / NM_001205301.2; = p.A864S on NM_152403.4) | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.047); catalogued as COSV100380371; called by muse, mutect2, varscan2
- EPHA5 | c.1228G>T p.G410C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV56680379, COSV56681598; called by muse, mutect2, varscan2
- ERCC4 | c.710T>C p.L237P | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100318929; called by muse, mutect2, varscan2
- ERCC6L | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs1219337943, COSV100559133; called by muse, mutect2
- FAM135B | c.4144G>T p.A1382S | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99424665; called by muse, mutect2, varscan2
- FAM135B | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99424670; called by muse, mutect2, varscan2
- FAM135B | c.1230G>T p.E410D | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99424675; called by muse, mutect2, varscan2
- FAM47A | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.607); catalogued as rs1337003755, COSV100649940, COSV100650107; called by muse, mutect2, varscan2
- FBN2 | c.5547A>T p.E1849D | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99328193; called by muse, mutect2, varscan2
- FCRL1 | c.125T>G p.F42C | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.203); catalogued as COSV100839812; called by muse, mutect2, varscan2
- FCRL5 | c.598C>A p.Q200K | Missense Mutation (SNP) | VAF 77/155 reads (50%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.839); catalogued as COSV62515874; called by muse, mutect2, varscan2
- FLG | c.5849C>G p.S1950* | Nonsense Mutation (SNP) | VAF 81/1658 reads (5%) | catalogued as rs200402044, COSV100911648; called by muse, mutect2
- FLRT2 | c.1373del p.G458Afs*4 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | catalogued as COSV100420783; called by mutect2, pindel, varscan2
- FPGT-TNNI3K | c.675G>C p.K225N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.804); catalogued as COSV100436868, COSV58564734; called by muse, mutect2, varscan2
- FSCN3 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as COSV50001843, COSV99133800; called by muse, mutect2, varscan2
- GAB4 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs775102283, COSV101271883, COSV101272003; called by muse, mutect2, varscan2
- GABRP | c.171T>A p.G57= | Splice Region (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99516844; called by muse, mutect2
- GALNT5 | c.2630A>T p.N877I | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as COSV52038208; called by muse, mutect2, varscan2
- GFM2 | c.1527G>C p.L509F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57190533, COSV99714438; called by muse, mutect2, varscan2
- GFUS | c.799G>T p.G267W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99643503; called by muse, mutect2, varscan2
- GFUS | c.798T>A p.H266Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV55308327, COSV99643506; called by muse, mutect2, varscan2
- GIMAP5 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100500257; called by muse, mutect2, varscan2
- GJD2 | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99290781; called by muse, mutect2, varscan2
- GPR174 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV99338181; called by muse, mutect2, varscan2
- GPR65 | c.400G>C p.V134L | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV99966085; called by muse, mutect2, varscan2
- GRIA1 | c.2578C>A p.P860T | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as COSV99598209, COSV99600376; called by muse, mutect2, varscan2
- GRIK2 | c.1207G>T p.G403* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100026844; called by muse, mutect2
- GRM3 | c.1018C>A p.L340I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as COSV100862596; called by muse, mutect2, varscan2
- GSG1L | c.847G>T p.G283W (on ENST00000447459 / NM_001109763.2; = p.G128W on NM_144675.2) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV101093567, COSV66580230; called by muse, mutect2, varscan2
- GTF3C5 | c.1437G>T p.Q479H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.215); catalogued as COSV100565443; called by muse, mutect2, varscan2
- HBE1 | c.422C>A p.A141D | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99496278; called by muse, mutect2, varscan2
- HDAC9 | c.1343G>T p.R448L | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV101286812, COSV67769445; called by muse, mutect2, varscan2
- HEPH | c.470C>G p.P157R (on ENST00000343002; = p.P211R on NM_138737.5) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100294998, COSV57970184; called by muse, mutect2, varscan2
- HHIP | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56840104, COSV99667357; called by muse, mutect2, varscan2
- IBSP | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as rs373947836; called by muse, mutect2, varscan2
- IBTK | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60390834, COSV60392717; called by mutect2, varscan2
- IFNL1 | c.170T>C p.L57S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100373652; called by muse, mutect2, varscan2
- IGHMBP2 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.017); catalogued as COSV99662153; called by muse, varscan2
- IGHMBP2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV99662157; called by muse, varscan2
- IGHMBP2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99662159; called by muse, mutect2, varscan2
- IL10RB | c.412A>G p.N138D | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99270043; called by muse, mutect2, varscan2
- IL7R | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100286319; called by muse, mutect2
- INPP5B | c.2287C>A p.L763M (on ENST00000373023; = p.L683M on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100886519, COSV65959572; called by muse, mutect2, varscan2
- JAG2 | c.206C>A p.T69K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100078508; called by muse, mutect2, varscan2
- KIF16B | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV100734443; called by muse, mutect2
- KIF26B | c.1073A>T p.K358M | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV101313937; called by muse, mutect2
- KIF26B | c.3138C>A p.S1046R | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100832662; called by muse, mutect2, varscan2
- KLB | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.162); catalogued as COSV99962220; called by muse, mutect2, varscan2
- KLF7 | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs146378446, COSV58742840; called by muse, mutect2, varscan2
- KLHL24 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV54429095; called by muse, mutect2, varscan2
- KLK6 | c.711C>G p.I237M | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100037712; called by muse, mutect2, varscan2
- KMT2D | c.3510del p.E1171Nfs*41 | Frame Shift Del (DEL) | VAF 29/107 reads (27%) | catalogued as COSV56489816; called by mutect2, pindel, varscan2
- KRT6B | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs199727604; called by muse, mutect2, varscan2
- KRT85 | c.11del p.R4Pfs*45 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as COSV57737864; called by mutect2, pindel, varscan2
- KRTAP10-3 | c.308T>C p.V103A | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100554067; called by muse, mutect2, varscan2
- LAMA1 | c.6589G>A p.D2197N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV101056636; called by muse, mutect2, varscan2
- LMF2 | c.1583G>T p.R528L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99327611; called by muse, mutect2, varscan2
- LPCAT1 | c.1366G>T p.V456L | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as COSV52038235; called by muse, mutect2, varscan2
- LRRC4C | c.664G>C p.D222H | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV53437898, COSV99538561; called by muse, mutect2, varscan2
- LSAMP | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100371000, COSV61292067; called by muse, mutect2, varscan2
- MAGEA3 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs1556826207, COSV100939060; called by muse, mutect2, varscan2
- MAGI1 | c.1043-2A>G p.X348_splice | Splice Site (SNP) | VAF 32/62 reads (52%) | catalogued as COSV100441407; called by muse, mutect2, varscan2
- MDN1 | c.12235C>T p.R4079C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1482210080, COSV101021450; called by muse, mutect2, varscan2
- MDN1 | c.11433G>T p.W3811C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101021451; called by muse, mutect2, varscan2
- MED14 | c.1121A>T p.H374L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV100247509; called by muse, varscan2
- MINDY3 | c.513G>T p.Q171H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.69); catalogued as COSV99510771; called by muse, mutect2, varscan2
- MINDY4 | c.1972G>C p.V658L | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99518788; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 6/79 reads (8%) | catalogued as COSV100825141, COSV64058050; called by muse, mutect2
- MPO | c.1727T>C p.V576A | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as COSV99228922; called by muse, mutect2, varscan2
- MTF2 | c.712A>G p.M238V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV100940133; called by muse, mutect2, varscan2
- MTMR1 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as COSV100953106; called by muse, mutect2, varscan2
- MUC16 | c.25710G>A p.M8570I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.048); catalogued as COSV67461991; called by muse, mutect2, varscan2
- MUC16 | c.21992G>A p.S7331N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.181); catalogued as COSV101200139; called by mutect2, varscan2
- MYB | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as COSV100214935, COSV57198781; called by muse, mutect2, varscan2
- MYH4 | c.3895G>A p.D1299N | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV55121677, COSV55124981; called by muse, mutect2, varscan2
- MYO3A | c.4218C>G p.I1406M | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.055); catalogued as COSV99780067; called by muse, mutect2, varscan2
- MYO9B | c.1344C>G p.I448M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV101261618; called by muse, mutect2, varscan2
- MYOCD | c.1786T>A p.C596S | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100590890; called by muse, mutect2, varscan2
- NIPBL | c.1066A>G p.T356A | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); catalogued as COSV99240966; called by muse, mutect2, varscan2
- NLRP5 | c.1880A>T p.H627L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV101173729; called by muse, mutect2, varscan2
- NLRP7 | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100051621; called by muse, mutect2, varscan2
- NOS1 | c.736G>T p.G246C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.426); catalogued as COSV99049338; called by muse, mutect2, varscan2
- NPHP4 | c.4261G>T p.V1421L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100976968; called by muse, mutect2, varscan2
- NPHS2 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100858180; called by muse, mutect2, varscan2
- NR1D2 | c.1557A>G p.I519M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.492); catalogued as COSV100437488; called by muse, varscan2
- NRP1 | c.1778C>G p.T593S | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.288); catalogued as COSV99588919; called by muse, mutect2, varscan2
- NTNG2 | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.279); catalogued as COSV100647511; called by muse, mutect2, varscan2
- NUDT13 | c.1023G>T p.W341C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100624781; called by mutect2, varscan2
- NUP50 | c.653A>T p.E218V | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV100754356; called by muse, mutect2, varscan2
- NUP50 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs748155873, COSV100754358; called by muse, mutect2, varscan2
- NYAP2 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56000764, COSV56005440; called by muse, mutect2, varscan2
- OCM | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1413308453, COSV99631430; called by muse, mutect2, varscan2
- OR10G8 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs372745744; called by muse, mutect2, varscan2
- OR10T2 | c.761G>C p.C254S | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1306776993, COSV100554981; called by muse, mutect2
- OR11G2 | c.264C>A p.H88Q | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100639970; called by muse, mutect2, varscan2
- OR11H12 | c.318C>A p.N106K | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1329556548, COSV101612499; called by mutect2, varscan2
- OR2M4 | c.927G>C p.K309N | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV100141287; called by muse, mutect2, varscan2
- OR2W3 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT tolerated (0.56); PolyPhen benign (0.262); catalogued as rs375894650; called by muse, mutect2, varscan2
- OR4F6 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100186933; called by muse, mutect2, varscan2
- OR4L1 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.421); catalogued as COSV100235747; called by muse, mutect2, varscan2
- OR6K2 | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100656810; called by muse, mutect2, varscan2
- OR8B4 | c.129G>T p.L43F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV100635825; called by muse, mutect2, varscan2
- PABPC5 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.346); catalogued as COSV100442426; called by muse, mutect2, varscan2
- PAPSS1 | c.1819G>C p.A607P | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99492112; called by muse, mutect2, varscan2
- PBX3 | c.941C>G p.T314R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as COSV100655487; called by muse, mutect2, varscan2
- PCDH11X | c.1181G>A p.G394D | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100012288; called by muse, mutect2, varscan2
- PCDH11X | c.3737G>T p.S1246I | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as COSV100007820, COSV100012291; called by muse, mutect2, varscan2
- PCDHGB2 | c.2222C>A p.P741H | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV99539951; called by muse, mutect2, varscan2
- PCDHGC5 | c.1587G>T p.M529I | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV99340576; called by muse, mutect2, varscan2
- PCNX2 | c.3664G>A p.D1222N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV99268095; called by muse, mutect2, varscan2
- PHKA1 | c.2248G>C p.E750Q | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.116); catalogued as COSV100263401; called by muse, mutect2, varscan2
- PIM2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557045088, COSV99900303; called by muse, mutect2, varscan2
- PIP4P1 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1472067050, COSV51658665; called by muse, mutect2
- PKD1 | c.9473G>A p.R3158K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.324); catalogued as COSV99238296; called by muse, mutect2, varscan2
- PKHD1L1 | c.5098T>A p.C1700S | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101006275; called by muse, mutect2
- PLXDC2 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV101024979, COSV65914772; called by muse, mutect2
- PNPLA6 | c.2491G>C p.D831H (on ENST00000414982 / NM_001166111.2; = p.D783H on NM_006702.5) | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs779192117, COSV55383276, COSV99653859; called by muse, mutect2, varscan2
- POLR2E | c.291G>T p.E97D | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV99297589; called by muse, mutect2, varscan2
- PROCA1 | c.64C>G p.R22G | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99972746, COSV99972775; called by muse, mutect2, varscan2
- PTCHD4 | c.2230C>G p.R744G | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1240265132, COSV100261031; called by muse, mutect2, varscan2
- PUM2 | c.2245G>C p.E749Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV100163725; called by mutect2, varscan2
- PYGO1 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 35/120 reads (29%) | catalogued as COSV100114677; called by muse, mutect2, varscan2
- RAB6D | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.382); catalogued as COSV72151660; called by muse, mutect2, varscan2
- RAD54L | c.1198C>T p.L400F | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100914794; called by muse, mutect2, varscan2
- RALYL | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV101569263; called by muse, mutect2, varscan2
- RAP1GAP | c.1507A>T p.I503F | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99265393; called by muse, mutect2, varscan2
- RASSF9 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770197276, COSV100771412; called by muse, mutect2, varscan2
- REV3L | c.2387A>G p.Y796C | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1007947508, COSV100725294; called by muse, mutect2, varscan2
- RGS7 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100468189; called by muse, mutect2, varscan2
- RNF6 | c.1226G>C p.G409A | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100644643; called by muse, mutect2, varscan2
- ROBO2 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100167347; called by muse, mutect2, varscan2
- RP1 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as rs774861777, COSV99607755; called by muse, mutect2, varscan2
- RP1L1 | c.5281G>T p.G1761W | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV101223311; called by muse, mutect2, varscan2
- RRP15 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.012); catalogued as rs200861386, COSV65117502; called by muse, mutect2, varscan2
- RUSC1 | c.1486G>A p.D496N (on ENST00000368352 / NM_001105203.2; = p.D27N on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV99429922; called by muse, mutect2, varscan2
- RXYLT1 | c.519G>C p.K173N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99706964; called by muse, mutect2, varscan2
- RYR2 | c.12403C>A p.R4135S | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100770893; called by muse, mutect2, varscan2
- SDK1 | c.3496A>T p.I1166F | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.844); catalogued as COSV101269475; called by muse, mutect2, varscan2
- SEZ6L | c.774C>A p.S258R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as COSV99962256; called by muse, mutect2
- SF3B3 | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs148340519; called by muse, mutect2, varscan2
- SGCE | c.1312C>A p.H438N (on ENST00000647096; = p.H402N on NM_003919.3) | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as COSV99722662; called by muse, mutect2, varscan2
- SHROOM4 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56788350, COSV99173619; called by muse, mutect2, varscan2
- SIPA1L3 | c.5035G>A p.D1679N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV55918607, COSV99729095; called by muse, mutect2, varscan2
- SIX5 | c.2104G>C p.E702Q | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV52181495, COSV52182384, COSV52183638; called by muse, mutect2, varscan2
- SLC32A1 | c.905A>T p.D302V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV99462340; called by muse, mutect2, varscan2
- SLC44A2 | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.409); catalogued as COSV100213261; called by muse, mutect2, varscan2
- SLFN12 | c.1317A>T p.K439N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100513110; called by muse, mutect2, varscan2
- SP5 | c.257C>G p.P86R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV100935303; called by muse, mutect2, varscan2
- SPG7 | c.1580G>T p.R527L (on ENST00000268704; = p.R534L on NM_003119.4) | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51947737; called by muse, mutect2, varscan2
- SPTA1 | c.5044G>C p.D1682H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV100935101; called by mutect2, varscan2
- SSTR5 | c.689C>A p.A230E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs371339888, COSV53513902, COSV99559473; called by muse, mutect2, varscan2
- STRADA | c.964G>T p.G322C (on ENST00000336174 / NM_001363786.1; = p.G285C on NM_153335.6) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99368617; called by muse, mutect2, varscan2
- SUSD6 | c.320-1G>C p.X107_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100713437; called by muse, mutect2, varscan2
- SV2B | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100370723; called by muse, mutect2, varscan2
- SYNE1 | c.11920G>T p.A3974S (on ENST00000367255 / NM_182961.4; = p.A3903S on NM_033071.3) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as COSV99567359; called by muse, mutect2, varscan2
- TANGO6 | c.2323A>T p.K775* | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | catalogued as COSV99936343; called by muse, mutect2, varscan2
- TBC1D9 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101464353; called by muse, mutect2, varscan2
- TCF20 | c.2981G>C p.R994T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100166664; called by muse, mutect2, varscan2
- TEX2 | c.2408C>A p.P803H (on ENST00000583097 / NM_001288733.2; = p.P810H on NM_018469.5) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1288618778, COSV99367175; called by muse, mutect2, varscan2
- TG | c.4676C>G p.P1559R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.289); catalogued as COSV99601365; called by muse, mutect2, varscan2
- TGDS | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.526); catalogued as COSV99725141; called by muse, mutect2, varscan2
- THSD7B | c.2653A>T p.T885S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.06); catalogued as COSV99752454; called by muse, mutect2, varscan2
- THSD7B | c.2924G>C p.G975A | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99752456; called by muse, mutect2
- TIGD7 | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99239896; called by muse, mutect2, varscan2
- TLR4 | c.1754G>A p.C585Y (on ENST00000355622 / NM_138554.5; = p.C545Y on NM_003266.4) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285033378, COSV100842779; called by muse, mutect2, varscan2
- TM2D2 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs1337130246, COSV101166138; called by muse, mutect2
- TMEM132B | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.225); catalogued as COSV100169924, COSV54772443; called by muse, mutect2, varscan2
- TMEM132D | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101398170, COSV70623392; called by muse, mutect2, varscan2
- TMEM161B | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 29/48 reads (60%) | catalogued as COSV99494582; called by muse, mutect2, varscan2
- TMEM252 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101051127, COSV66065861; called by muse, mutect2, varscan2
- TMEM61 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 41/116 reads (35%) | catalogued as COSV100987751; called by muse, mutect2, varscan2
- TRAV26-1 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 73/129 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as rs749761824; called by muse, mutect2, varscan2
- TRIM3 | c.1054G>T p.G352W | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100624435; called by muse, mutect2, varscan2
- TRIM58 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100825130; called by muse, mutect2, varscan2
- TRIO | c.6153C>T p.H2051= | Splice Region (SNP) | VAF 9/41 reads (22%) | catalogued as rs746238974, COSV100710069, COSV60079572; called by muse, mutect2, varscan2
- TRO | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as COSV99436607; called by muse, mutect2, varscan2
- TTC14 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 46/718 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV99869284; called by muse, mutect2
- TTC7A | c.764+1G>C p.X255_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | catalogued as CD137047, COSV99766533; called by muse, mutect2, varscan2
- TTN | c.58057T>C p.S19353P (on ENST00000591111; = p.S11929P on NM_003319.4) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | PolyPhen probably damaging (0.961); catalogued as COSV100617082; called by muse, mutect2, varscan2
- TTN | c.11602T>C p.F3868L (on ENST00000591111; = p.F3822L on NM_003319.4) | Missense Mutation (SNP) | VAF 7/73 reads (10%) | catalogued as COSV100617086; called by muse, mutect2, varscan2
- TULP1 | c.602-1G>T p.X201_splice | Splice Site (SNP) | VAF 55/109 reads (50%) | catalogued as COSV100004215; called by muse, mutect2, varscan2
- TUT7 | c.3004G>C p.D1002H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV99463151; called by muse, mutect2, varscan2
- UBXN4 | c.1468C>G p.Q490E | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.427); catalogued as COSV99739272; called by muse, mutect2, varscan2
- UIMC1 | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.775); catalogued as COSV101022178; called by muse, mutect2, varscan2
- UNC13C | c.5038G>A p.D1680N | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs867388287, COSV99518542; called by muse, mutect2
- UNC93A | c.988C>A p.H330N | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100023358; called by muse, mutect2, varscan2
- UTP14C | c.2263C>T p.R755* | Nonsense Mutation (SNP) | VAF 17/122 reads (14%) | catalogued as rs201468648, COSV101584314; called by muse, mutect2, varscan2
- UTRN | c.6061C>A p.L2021I | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100839978; called by muse, mutect2, varscan2
- VPS54 | c.1635G>T p.E545D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV99708230; called by muse, mutect2, varscan2
- VWF | c.3751C>T p.P1251S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.553); catalogued as COSV99779309; called by muse, mutect2, varscan2
- WDR72 | c.713T>A p.V238D | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100854590; called by muse, mutect2, varscan2
- WNK1 | c.2728G>T p.V910F | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.265); catalogued as COSV100267636; called by muse, mutect2, varscan2
- WWP2 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV100598592, COSV63124040; called by muse, mutect2, varscan2
- ZACN | c.974C>A p.A325D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs772741101, COSV100135366; called by muse, mutect2
- ZAN | c.6410C>A p.A2137E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100769827, COSV61811568; called by muse, mutect2, varscan2
- ZEB1 | c.178G>T p.D60Y | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100314528; called by muse, mutect2, varscan2
- ZIM2 | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 24/61 reads (39%) | catalogued as COSV55630713; called by muse, mutect2, varscan2
- ZNF107 | c.1981G>C p.E661Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100788409; called by muse, mutect2, varscan2
- ZNF208 | c.3511T>C p.C1171R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101237053; called by muse, mutect2, varscan2
- ZNF208 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101237054; called by muse, mutect2, varscan2
- ZNF384 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.288); catalogued as COSV100158578; called by muse, mutect2, varscan2
- ZNF496 | c.225G>T p.R75S | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99665771; called by muse, mutect2, varscan2
- ZNF496 | c.224G>T p.R75M | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99665775; called by muse, mutect2, varscan2
- ZNF547 | c.1040C>G p.T347S | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV99987990; called by muse, mutect2
- ZNF576 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); catalogued as rs1454619340, COSV100338174; called by muse, mutect2, varscan2
- ZNF600 | c.1369C>T p.L457F | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100593010; called by muse, mutect2
- ZNF676 | c.148C>A p.P50T (on ENST00000650058; = p.P18T on NM_001001411.3) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV101236228; called by muse, mutect2, varscan2
- ANK1 | c.3897del p.N1300Tfs*5 | Frame Shift Del (DEL) | VAF 34/132 reads (26%) | called by mutect2, pindel, varscan2
- CCN4 | c.451del p.V151Wfs*23 | Frame Shift Del (DEL) | VAF 19/110 reads (17%) | called by mutect2, pindel, varscan2
- CDKL2 | c.682del p.L228Ffs*11 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- DENND5A | c.3453_3464del p.Q1152_F1155del | In Frame Del (DEL) | VAF 35/91 reads (38%) | called by mutect2, pindel, varscan2
- EPHA6 | c.2258C>G p.P753R (on ENST00000389672 / NM_001080448.3; = p.P145R on NM_173655.4) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- EVPL | c.2085_2086del p.L696Efs*65 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by pindel, varscan2
- GAS2L1 | c.420del p.L141Wfs*60 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- IGBP1P2 | c.991A>T p.R331W | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- IGF2BP2 | c.60del p.Q21Sfs*16 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- ITPRID1 | c.2319dup p.H774Tfs*18 | Frame Shift Ins (INS) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- KIF2A | c.1362_1368del p.L455Ifs*30 | Frame Shift Del (DEL) | VAF 30/52 reads (58%) | called by mutect2, pindel, varscan2
- MMP15 | c.769del p.A257Qfs*63 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- PCDHB9 | c.1712C>A p.P571H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PNISR | c.449del p.G150Vfs*12 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- PPP2R1A | c.973_974delinsT p.Q325* | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by pindel, varscan2*
- TLR8 | c.1725_1726insAAATT p.H576Kfs*4 (on ENST00000218032 / NM_138636.5; = p.H594Kfs*4 on NM_016610.4) | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | called by mutect2, pindel*, varscan2
- TRPS1 | c.3840del p.E1281Sfs*11 (on ENST00000220888 / NM_001330599.2; = p.E1294Sfs*11 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- WASHC2C | c.3172G>T p.D1058Y (on ENST00000336378; = p.D1037Y on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- WDR19 | c.1422dup p.K475* | Frame Shift Ins (INS) | VAF 45/108 reads (42%) | called by mutect2, pindel, varscan2
- AAAS | c.624C>G p.V208= | Silent (SNP) | VAF 7/132 reads (5%) | catalogued as COSV99266997; called by muse, mutect2
- ABCC3 | c.528C>T p.I176= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV99559284; called by muse, mutect2, varscan2
- ABHD12B | c.478C>T p.L160= (on ENST00000337334 / NM_001206673.2; = p.L83= on NM_181533.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/109 reads (42%) | catalogued as rs746573105, COSV100485701; called by muse, mutect2, varscan2
- ADGRG4 | c.2817A>G p.A939= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as rs1479912152, COSV99795743; called by muse, mutect2, varscan2
- AFG3L2 | c.1065G>A p.T355= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs139181972; called by muse, mutect2, varscan2
- AGRN | c.1473G>A p.L491= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs750394972, COSV101038910; called by muse, varscan2
- AKAP13 | c.3819G>T p.G1273= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100773935; called by muse, mutect2, varscan2
- ANKFN1 | c.744G>T p.L248= | Silent (SNP) | VAF 25/162 reads (15%) | catalogued as COSV100593614; called by muse, mutect2, varscan2
- ARHGEF15 | c.969T>A p.P323= | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as COSV100730059; called by muse, mutect2, varscan2
- AXIN1 | c.1947C>T p.T649= | Silent (SNP) | VAF 49/119 reads (41%) | catalogued as rs148792863; called by muse, mutect2, varscan2
- C2orf16 | c.1140C>A p.P380= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV101284398; called by muse, mutect2, varscan2
- C6 | c.18C>T p.V6= | Silent (SNP) | VAF 43/152 reads (28%) | catalogued as COSV54710135; called by muse, mutect2, varscan2
- CACNA1I | c.573C>T p.R191= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as rs764399264, COSV100360547; called by muse, mutect2, varscan2
- CAMSAP1 | c.2571G>A p.Q857= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100409966; called by muse, mutect2, varscan2
- CAPN3 | c.1809C>T p.I603= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV99782712; called by muse, mutect2, varscan2
- CBX3 | c.90T>C p.F30= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs778109690, COSV100522959; called by muse, mutect2, varscan2
- CDH23 | c.903G>C p.R301= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs1427040866, COSV99820926, COSV99821493; called by muse, mutect2, varscan2
- CFAP20 | c.231C>A p.V77= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99343502; called by muse, mutect2, varscan2
- CFAP47 | c.147C>T p.F49= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs1245551011, COSV99935190; called by muse, mutect2, varscan2
- CILK1 | c.87G>C p.L29= | Silent (SNP) | VAF 6/122 reads (5%) | catalogued as COSV100607785, COSV63153533, COSV63155120; called by muse, mutect2
- CLP1 | c.405C>G p.L135= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100239646, COSV100239833, COSV57054118; called by muse, mutect2
- COL21A1 | c.610A>C p.R204= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV99778974; called by muse, mutect2, varscan2
- COL4A1 | c.1152T>A p.P384= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV101011254; called by muse, mutect2, varscan2
- COL6A3 | c.7264C>A p.R2422= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as COSV99798873; called by muse, mutect2, varscan2
- COL6A3 | c.3531C>T p.T1177= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99798877; called by muse, mutect2, varscan2
- COPB1 | c.1596C>T p.P532= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99999661; called by muse, mutect2, varscan2
- CPA6 | c.1093C>A p.R365= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV52731124, COSV99913777; called by muse, mutect2
- DIP2A | c.3570G>A p.Q1190= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100595953; called by muse, mutect2, varscan2
- DNAH2 | c.8310T>C p.S2770= | Silent (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- DNAH8 | c.7449A>G p.L2483= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as rs941878442, COSV100545779; called by muse, mutect2, varscan2
- DSCAM | c.5091G>A p.Q1697= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV101260415; called by muse, mutect2, varscan2
- EEF2K | c.1251C>T p.D417= | Silent (SNP) | VAF 23/144 reads (16%) | catalogued as COSV99533264; called by muse, mutect2, varscan2
- EML3 | c.1488C>T p.G496= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99609955; called by muse, mutect2, varscan2
- ESRRG | c.1272G>A p.L424= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100753160; called by muse, mutect2, varscan2
- EXOC6B | c.660C>T p.A220= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99724676; called by muse, mutect2, varscan2
- FBXO34 | c.288C>T p.I96= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs759950687, COSV100571979; called by muse, mutect2, varscan2
- FCGBP | c.11421G>A p.V3807= | Silent (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- FLNC | c.3612C>T p.I1204= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100368235; called by muse, mutect2, varscan2
- FMN1 | c.2241G>T p.R747= (on ENST00000616417 / NM_001277313.2; = p.R524= on NM_001103184.4) | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100568809; called by muse, mutect2, varscan2
- FSCN3 | c.870C>G p.R290= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV99133801; called by muse, mutect2
- GIMAP5 | c.144T>C p.L48= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100500256; called by muse, mutect2, varscan2
- HOGA1 | c.792T>C p.D264= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV101035544; called by muse, mutect2, varscan2
- IFT122 | c.3003C>T p.T1001= (on ENST00000348417 / NM_052989.3; = p.T942= on NM_018262.4) | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs757583043, COSV99959430; called by muse, mutect2, varscan2
- IGFN1 | c.3249G>A p.A1083= (on ENST00000295591 / NM_001367841.1; = p.A3540= on NM_001164586.2) | Silent (SNP) | VAF 45/88 reads (51%) | catalogued as rs779335394, COSV55179979, COSV99811946; called by muse, mutect2, varscan2
- IGHMBP2 | c.732C>T p.S244= | Silent (SNP) | VAF 23/303 reads (8%) | catalogued as COSV99662162; called by muse, mutect2
- IL10 | c.30G>C p.L10= | Silent (SNP) | VAF 35/65 reads (54%) | catalogued as rs762421652, COSV100894752, COSV100894766; called by muse, mutect2, varscan2
- ITPR3 | c.1176C>G p.L392= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV100967488, COSV65408863; called by muse, mutect2, varscan2
- KANK1 | c.1866C>G p.L622= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100619896; called by muse, mutect2, varscan2
- KCTD19 | c.2718C>T p.I906= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100431004; called by muse, mutect2, varscan2
- KLK1 | c.153G>T p.G51= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100032768; called by muse, mutect2, varscan2
- MAP2 | c.1428C>T p.S476= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs754008328, COSV99560396; called by muse, mutect2, varscan2
- MAPKBP1 | c.687A>T p.L229= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV99529648; called by muse, mutect2, varscan2
- MED13 | c.2880C>T p.I960= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV101181139; called by muse, mutect2, varscan2
- MEFV | c.2154G>A p.V718= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as rs1280453006, COSV99560989; called by muse, mutect2, varscan2
- MGAT5 | c.813C>G p.L271= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99924600; called by mutect2, varscan2
- MYH2 | c.1644C>T p.D548= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV99820335; called by muse, varscan2
- NRL | c.405G>C p.A135= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99393507; called by muse, mutect2
- NUP43 | c.48C>G p.T16= | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as COSV100462130; called by muse, mutect2
- OLFML2B | c.720A>T p.P240= | Silent (SNP) | VAF 62/129 reads (48%) | catalogued as COSV99668523; called by muse, mutect2, varscan2
- OR1K1 | c.297G>A p.L99= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as rs1384288812, COSV99474301; called by muse, mutect2, varscan2
- OR2W1 | c.624C>G p.L208= | Silent (SNP) | VAF 48/90 reads (53%) | catalogued as COSV101013917; called by muse, mutect2, varscan2
- OR56A3 | c.75C>A p.P25= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV100289997, COSV100290265; called by muse, mutect2, varscan2
- OR8D4 | c.366C>G p.R122= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as rs769052119; called by muse, mutect2, varscan2
- PBX3 | c.420A>T p.G140= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as COSV100655486; called by muse, mutect2, varscan2
- PCDHA8 | c.2076G>T p.A692= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as COSV65325006, COSV65331587; called by muse, mutect2, varscan2
- PCDHGA7 | c.2100C>A p.V700= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV99539954; called by muse, mutect2, varscan2
- PCLO | c.11508C>T p.D3836= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV100433525, COSV61638870; called by muse, mutect2, varscan2
- PCNX3 | c.3264G>T p.G1088= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100856469; called by muse, mutect2, varscan2
- PCOLCE2 | c.957C>A p.A319= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV99930744; called by muse, mutect2, varscan2
- PDZRN3 | c.2823C>A p.R941= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV99730117; called by muse, mutect2, varscan2
- PERP | c.541C>T p.L181= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV101408593; called by muse, mutect2, varscan2
- PI4K2A | c.12G>T p.T4= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV101034270; called by muse, mutect2
- PKD1L1 | c.7740T>C p.V2580= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV99220070; called by muse, mutect2, varscan2
- POLD1 | c.2580G>T p.A860= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV54532184; called by muse, mutect2, varscan2
- POLR1G | c.1029G>A p.G343= | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as COSV99185309; called by muse, mutect2
- PTGES2 | c.306G>T p.L102= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV52968627, COSV99476383; called by muse, mutect2, varscan2
- RBFOX1 | c.978C>T p.A326= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs146803665, COSV100301782; called by muse, mutect2, varscan2
- RECQL | c.651T>A p.A217= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100131286; called by muse, mutect2, varscan2
- SATB2 | c.1848G>A p.R616= | Silent (SNP) | VAF 41/118 reads (35%) | catalogued as COSV99611462; called by muse, mutect2, varscan2
- SCN9A | c.2055C>G p.L685= (on ENST00000303354; = p.L674= on NM_002977.3) | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as rs202048023, COSV100313101; called by muse, mutect2, varscan2
- SI | c.3268C>T p.L1090= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100015852; called by muse, mutect2, varscan2
- SLC12A9 | c.699G>T p.P233= | Silent (SNP) | VAF 57/168 reads (34%) | catalogued as COSV99307533; called by muse, mutect2, varscan2
- SLC22A2 | c.207G>A p.E69= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs367567495; called by muse, mutect2, varscan2
- SLC30A1 | c.183C>T p.A61= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV100879164; called by muse, mutect2
- SLC35A2 | c.171C>G p.A57= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99900300; called by muse, mutect2, varscan2
- SOHLH2 | c.27G>A p.E9= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100499424, COSV58521510; called by muse, mutect2, varscan2
- SOX10 | c.1248C>A p.G416= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV100704142; called by muse, mutect2, varscan2
- SPG7 | c.1581G>T p.R527= (on ENST00000268704; = p.R534= on NM_003119.4) | Silent (SNP) | VAF 22/135 reads (16%) | catalogued as COSV99245015; called by muse, mutect2, varscan2
- SPHKAP | c.3963C>T p.N1321= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as rs758501786, COSV100764187; called by muse, mutect2, varscan2
- SV2B | c.1656G>A p.G552= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as COSV100370617, COSV100370725; called by muse, mutect2, varscan2
- TAAR8 | c.750G>A p.K250= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99034073, COSV99257226; called by muse, mutect2, varscan2
- TANGO6 | c.2322G>T p.G774= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV99936342; called by muse, mutect2, varscan2
- THEMIS | c.1188G>T p.T396= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100965420; called by muse, mutect2, varscan2
- TMED4 | c.321C>G p.P107= | Silent (SNP) | VAF 44/129 reads (34%) | catalogued as rs537643590, COSV99215558; called by muse, mutect2, varscan2
- TMEM169 | c.366C>T p.V122= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV99824522; called by muse, mutect2, varscan2
- TMOD2 | c.132C>G p.A44= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99987807; called by muse, mutect2, varscan2
- TRAM2 | c.36C>G p.L12= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV51732329; called by muse, mutect2, varscan2
- TRAP1 | c.996G>A p.K332= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV99893503; called by muse, mutect2, varscan2
- TRH | c.628C>T p.L210= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100234855; called by muse, mutect2, varscan2
- TRO | c.2805C>T p.T935= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99436608; called by muse, mutect2, varscan2
- WNK3 | c.3057C>A p.S1019= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100671546; called by muse, mutect2, varscan2
- XIRP2 | c.8907C>A p.S2969= (on ENST00000628543; = p.S3144= on NM_152381.6) | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as COSV99743792; called by muse, mutect2, varscan2
- ZDHHC8 | c.498C>T p.F166= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs757892149, COSV100272913, COSV57708831; called by muse, mutect2, varscan2
- ZFHX4 | c.1116T>C p.G372= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs767174337, COSV51509501; called by muse, mutect2, varscan2
- ZNF534 | c.417A>T p.V139= (on ENST00000332323 / NM_001143939.3; = p.V126= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99989858; called by muse, mutect2, varscan2
- ZNF587 | c.1419T>C p.F473= | Silent (SNP) | VAF 29/164 reads (18%) | catalogued as COSV100299529; called by muse, mutect2, varscan2
- ZNF608 | c.2880A>G p.S960= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs761279383, COSV100101829; called by muse, mutect2, varscan2
- CCNP | c.514-76G>T | Intron (SNP) | VAF 31/136 reads (23%) | catalogued as COSV99695886; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85346G>C | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- NETO1 | c.29-357G>T | Intron (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100198896; called by muse, mutect2, varscan2
- RERE | c.830+15441A>T | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100556666; called by mutect2, varscan2
- SNORD116-22 | n.6G>T | RNA (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2, varscan2
- SNX29P2 | n.958C>T | RNA (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2, varscan2
- SSR4 | c.*1G>T | 3'UTR (SNP) | VAF 6/8 reads (75%) | catalogued as COSV99381405, COSV99381764; called by muse, mutect2
- TTN | c.10360+4836C>G | Intron (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100617087; called by muse, mutect2, varscan2
